Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A64S, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A64S-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A-C. Brain, right frontal #1-#3, biopsies: Low grade oligoastrocytoma (WHO grade II), astrocytic predominant.

Special Stains:

Neurofilament: The tumor demonstrates an infiltrative pattern of growth.

p53: Moderate to high labeling.

Ki67/MIB-1: Low to moderate labeling index.

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the
For interpretation, see Synthesis in Labs under Genetics

Seen in consultation with

Interpreted by:
Report electronically signed b

Transcribed by:

Preliminary Frozen Section Consultation:

A. Brain, right frontal #1, smears: Low-grade glial lesion with oligodendroglial features. Hold over for

ALL EMBEDDED

continued next page Page 1 of 2

ICD O-3

Oligoastrocytoma 9382/3
Site R Brain, frontal lobe
C6CF C71.1
Brain, supratentorial NOS
C71.0

[page 2 of 2]
classification on permanent sections.

Intraoperative cytologic smear(s) interpretation performed by:

Gross Description:

A. Received fresh labeled "right frontal brain" is a 2.5 x 2.3 x 0.7 cm portion of brain. Smears prepared. All submitted. Grossed by

B. Received fresh labeled "deep right frontal white matter - brain" is a 2.5 x 1.6 x 0.4 cm aggregate of neural tissue. Smears prepared. All submitted for permanent sections only. Grossed by

C. Received fresh labeled "right frontal lesion #2 - brain" is a 1.6 x 0.6 x 0.3 cm aggregate of neural tissue. Smears prepared. All submitted for permanent sections only. Grossed by

Block Summary:

Part A: Right frontal lesion - brain

- 1 Rt frontal lesion 1
- 2 Rt frontal lesion 2
- 3 Rt frontal lesion 3
- 4 Rt frontal lesion 4

Part B: Deep right frontal white matter - brain

- 1 Deep rt frontal brain 1
- 2 Deep rt frontal brain 2
- 3 Deep rt frontal brain 3

Part C: Right frontal lesion #2 - brain

- 1 Rt frontal lesion #2-1
- 2 Rt frontal lesion #2-2

ALL EMBEDDED

END OF REPORT

Page 2 of 2

Primary Tumor Discrepancy		✓
IIH/PA Discrepancy		✓

4/2/13

Source: NCI Genomic Data Commons file d8ed45b7-a9b1-49b7-be62-80061c251a26 (TCGA-DB-A64S.31AB0B8C-9300-4508-B653-CB898986E68F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).